Somatic mutation profile of tumor specimen TCGA-B0-5701-01A (aliquot TCGA-B0-5701-01A-11D-1534-10) from TCGA case TCGA-B0-5701, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 65.5 years (23,915 days).
Specimen TCGA-B0-5701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c62c52d-1e4e-420b-87fc-3376b615c57d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5701-11A (Solid Tissue Normal), aliquot TCGA-B0-5701-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14be6489-cd48-4c6e-91c6-0a01c4886100

The open-access MAF lists 104 somatic variants for this specimen: 81 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 22, Frame Shift Del 11, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNA1 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs1554085478, COSV57079787; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AGO3 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs372140569; called by muse, mutect2, varscan2
- ALAS1 | c.54T>G p.F18L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV59629339; called by muse, mutect2, varscan2
- ARAP2 | c.2462T>C p.V821A | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV58290892; called by muse, mutect2
- ASNSD1 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 112/375 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53622889, COSV53624613; called by muse, mutect2, varscan2
- ASXL1 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60118043; called by muse, mutect2, varscan2
- BCORL1 | c.1075A>C p.T359P | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV54404149; called by muse, mutect2, varscan2
- BPTF | c.8352G>A p.M2784I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58844532; called by muse, mutect2, varscan2
- BPTF | c.8353C>G p.Q2785E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58844551; called by muse, mutect2, varscan2
- CCDC73 | c.1283A>T p.E428V | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as COSV58803299; called by muse, mutect2, varscan2
- CNIH4 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 70/1096 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV64796441; called by muse, mutect2
- COL2A1 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs751436440, COSV61533186; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56007715; called by muse, mutect2
- CPSF4 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV52858930; called by muse, mutect2, varscan2
- CSMD3 | c.11062T>C p.S3688P (on ENST00000297405 / NM_001363185.1; = p.S3519P on NM_052900.3) | Missense Mutation (SNP) | VAF 225/770 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.342); catalogued as COSV52283544; called by muse, mutect2, varscan2
- DEFB116 | c.147C>A p.N49K | Missense Mutation (SNP) | VAF 208/726 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); catalogued as COSV68722362; called by muse, mutect2, varscan2
- DENND1C | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV57568717; called by muse, mutect2, varscan2
- DNAH2 | c.2714_2715del p.S905Cfs*7 | Frame Shift Del (DEL) | VAF 88/342 reads (26%) | catalogued as rs766303944; called by pindel, varscan2
- DOCK11 | c.3458G>T p.R1153I | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52245783; called by muse, mutect2, varscan2
- DUOX1 | c.3890G>C p.G1297A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as COSV104394844, COSV58485225; called by muse, mutect2
- DYNC2H1 | c.6936A>T p.Q2312H | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV62103712; called by muse, mutect2, varscan2
- ECH1 | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV55490117; called by muse, mutect2, varscan2
- EPHA6 | c.331T>A p.L111M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV67589646; called by muse, mutect2, varscan2
- FAM170A | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV58926725; called by muse, mutect2, varscan2
- FLT4 | c.3731C>T p.A1244V | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1230678706, COSV56108806; called by muse, mutect2, varscan2
- GATAD2A | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53074396; called by muse, mutect2
- GPATCH8 | c.1887A>T p.R629S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV59197465; called by muse, mutect2, varscan2
- HPSE | c.744A>T p.Q248H | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV60988254; called by muse, mutect2, varscan2
- KIDINS220 | c.3296C>A p.P1099Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as rs763733199, COSV56750912, COSV56757905; called by muse, mutect2, varscan2
- KMT2B | c.1318C>G p.P440A | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV52892122; called by muse, mutect2, varscan2
- KMT2D | c.14268A>T p.K4756N | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV56475322; called by muse, mutect2, varscan2
- KPNA2 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV57858637; called by muse, mutect2, varscan2
- KRTAP5-5 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | PolyPhen probably damaging (0.972); catalogued as COSV68785559; called by muse, mutect2, varscan2
- LACRT | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 102/366 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as COSV57688607; called by muse, mutect2, varscan2
- LCOR | c.2981T>G p.V994G | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53717887; called by muse, mutect2, varscan2
- MAP3K12 | c.1322T>C p.M441T | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV57235263; called by muse, mutect2, varscan2
- MCPH1 | c.1568A>G p.N523S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1175866566, COSV60918230; called by muse, mutect2, varscan2
- MSTN | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV99640730; called by muse, mutect2
- NEB | c.9938A>G p.Q3313R | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.415); catalogued as COSV51449384; called by muse, mutect2, varscan2
- NET1 | c.1208T>C p.I403T (on ENST00000355029 / NM_001047160.3; = p.I349T on NM_005863.5) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV61792409; called by mutect2, varscan2
- NLRP2 | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 108/390 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV54757094, COSV54759102; called by muse, mutect2, varscan2
- NUDT7 | c.639A>C p.Q213H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV51746807; called by muse, mutect2, varscan2
- OR13C8 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 203/467 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV58612109; called by muse, mutect2, varscan2
- OR5M1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as COSV73202095; called by muse, mutect2, varscan2
- PIK3R4 | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV63243336; called by muse, mutect2, varscan2
- PILRA | c.892T>A p.Y298N | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52200218, COSV52202144; called by muse, mutect2, varscan2
- PLSCR4 | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61608834; called by muse, mutect2, varscan2
- PPRC1 | c.2908G>A p.V970I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV53387756; called by muse, mutect2, varscan2
- PRDM14 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV52574870; called by muse, mutect2, varscan2
- PTH1R | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV57317353; called by muse, mutect2, varscan2
- RABEP1 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52587595; called by muse, mutect2, varscan2
- RAD54L | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.04); catalogued as COSV64336814; called by muse, mutect2, varscan2
- RGS12 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60908856; called by muse, mutect2, varscan2
- SASS6 | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 129/471 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54929664; called by muse, mutect2, varscan2
- SPP1 | c.904A>G p.I302V (on ENST00000395080 / NM_001040058.2; = p.I288V on NM_000582.2) | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1461957441, COSV52952567; called by muse, mutect2, varscan2
- STRN3 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62581416; called by muse, mutect2, varscan2
- SVIL | c.2250A>C p.E750D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs1232531256, COSV63446993; called by muse, mutect2, varscan2
- SYNE1 | c.12087G>T p.Q4029H (on ENST00000367255 / NM_182961.4; = p.Q3958H on NM_033071.3) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV55070776; called by muse, mutect2, varscan2
- TAS1R2 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as rs769512571, COSV64744295; called by muse, mutect2, varscan2
- TEX2 | c.4A>T p.T2S | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.1); catalogued as COSV51984732; called by muse, mutect2, varscan2
- TICAM1 | c.911G>C p.C304S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV50237833; called by muse, mutect2, varscan2
- TMOD1 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52251657; called by muse, mutect2, varscan2
- TRAPPC8 | c.3279T>G p.N1093K | Missense Mutation (SNP) | VAF 108/404 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV51976158; called by muse, mutect2, varscan2
- TRIM37 | c.2714A>C p.D905A | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51887701; called by muse, mutect2, varscan2
- TUBB2B | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.058); catalogued as COSV52534286; called by muse, mutect2, varscan2
- UAP1L1 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183320631, COSV64306838; called by muse, mutect2, varscan2
- ZNF207 | c.938C>A p.T313K | Missense Mutation (SNP) | VAF 128/501 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as COSV58301564; called by muse, mutect2, varscan2
- ZNF584 | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as COSV59723191; called by muse, mutect2, varscan2
- ARHGAP30 | c.1582_1583del p.D528Wfs*46 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- BRF2 | c.302_303dup p.R102Ifs*23 | Frame Shift Ins (INS) | VAF 22/94 reads (23%) | called by mutect2, pindel, varscan2
- EIF2B3 | c.1012_1022del p.P338Ffs*14 | Frame Shift Del (DEL) | VAF 47/272 reads (17%) | called by mutect2, pindel, varscan2
- EML5 | c.2108_2111delinsGCAC p.V703_Y704delinsGT | Missense Mutation (ONP) | VAF 21/91 reads (23%) | called by pindel, varscan2*
- GPR179 | c.6070_6082del p.V2024Sfs*85 (on ENST00000621958; = p.V2023Sfs*85 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 45/179 reads (25%) | called by mutect2, pindel, varscan2
- MRPS6 | c.205del p.Y69Mfs*18 | Frame Shift Del (DEL) | VAF 90/374 reads (24%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.3392del p.N1131Tfs*76 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- OAS1 | c.1091_1092del p.K364Ifs*8 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- PCDHB11 | c.1044dup p.V349Cfs*21 | Frame Shift Ins (INS) | VAF 45/255 reads (18%) | called by mutect2, pindel, varscan2
- PIP4P2 | c.618del p.V207Lfs*3 | Frame Shift Del (DEL) | VAF 47/222 reads (21%) | called by mutect2, pindel, varscan2
- SDAD1 | c.358del p.E120Nfs*23 | Frame Shift Del (DEL) | VAF 79/330 reads (24%) | called by mutect2, pindel, varscan2
- USP45 | c.1211del p.L404Yfs*15 | Frame Shift Del (DEL) | VAF 65/299 reads (22%) | called by mutect2, pindel, varscan2
- ZNF606 | c.1809del p.A604Hfs*13 | Frame Shift Del (DEL) | VAF 37/173 reads (21%) | called by mutect2, pindel, varscan2
- ADGRA1 | c.1245C>A p.T415= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV63416795; called by muse, mutect2, varscan2
- ATG4B | c.726G>T p.T242= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV60352543; called by muse, mutect2, varscan2
- BBX | c.687C>T p.C229= | Silent (SNP) | VAF 44/184 reads (24%) | catalogued as rs1262051031, COSV57892271; called by muse, varscan2
- CAPN12 | c.300G>A p.G100= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV61018008; called by muse, mutect2, varscan2
- CDH11 | c.135G>A p.G45= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV51773313; called by muse, mutect2, varscan2
- CEP164 | c.1158G>A p.L386= | Silent (SNP) | VAF 79/290 reads (27%) | catalogued as rs199723361, COSV54045301; called by muse, mutect2, varscan2
- HPS4 | c.1659G>C p.L553= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61104894; called by muse, mutect2, varscan2
- KCNG2 | c.1116C>T p.Y372= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs778122961, COSV60268830; called by muse, varscan2
- LRPPRC | c.1704A>T p.G568= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV53242014; called by muse, mutect2, varscan2
- LTBP4 | c.4239G>T p.P1413= (on ENST00000308370 / NM_001042544.1; = p.P1376= on NM_003573.2) | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs760319724, COSV52579576, COSV52588456; called by muse, varscan2
- NAV1 | c.3630A>G p.K1210= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as COSV55223920; called by muse, mutect2, varscan2
- NCAPH2 | c.438C>T p.P146= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV55371222; called by muse, mutect2, varscan2
- OR10G7 | c.546C>G p.P182= | Silent (SNP) | VAF 56/252 reads (22%) | catalogued as COSV57868428; called by muse, mutect2, varscan2
- OR52W1 | c.342C>A p.A114= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV60951552; called by muse, mutect2, varscan2
- PLCH1 | c.1956C>T p.L652= (on ENST00000340059 / NM_001130960.2; = p.L664= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 141/521 reads (27%) | catalogued as rs779404905, COSV58207732; called by muse, mutect2, varscan2
- PTCH2 | c.3423T>A p.L1141= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1236126581, COSV63400361; called by muse, mutect2, varscan2
- ROPN1B | c.636G>A p.E212= | Silent (SNP) | VAF 68/327 reads (21%) | catalogued as rs1289977447, COSV52543122; called by muse, mutect2, varscan2
- SALL1 | c.1326C>G p.S442= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV51762903; called by muse, mutect2, varscan2
- SMARCC2 | c.1605T>C p.A535= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs941137554, COSV57223262; called by muse, mutect2
- TECTA | c.1041G>A p.L347= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV50776208; called by muse, mutect2, varscan2
- TFB2M | c.1005A>G p.V335= | Silent (SNP) | VAF 63/311 reads (20%) | catalogued as COSV63625108; called by muse, mutect2, varscan2
- TTN | c.70527G>A p.Q23509= (on ENST00000591111; = p.Q16085= on NM_003319.4) | Silent (SNP) | VAF 111/418 reads (27%) | catalogued as rs1189168893, COSV60272582; ClinVar: likely benign; called by muse, mutect2, varscan2
- DSC2 | c.2509-101A>C | Intron (SNP) | VAF 72/274 reads (26%) | catalogued as COSV51868096; called by muse, mutect2, varscan2
